Somatic mutation profile of tumor specimen TCGA-CK-6748-01A (aliquot TCGA-CK-6748-01A-11D-1835-10) from TCGA case TCGA-CK-6748, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 45.3 years (16,529 days).
Specimen TCGA-CK-6748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7df9f85b-d723-467c-8c1a-25f3f89a4d31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-6748-10A (Blood Derived Normal), aliquot TCGA-CK-6748-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a6709e7-91a3-4541-89fd-b1dd292a3485

The open-access MAF lists 68 somatic variants for this specimen: 45 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 22, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, RNA 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3944C>A p.S1315* | Nonsense Mutation (SNP) | VAF 91/106 reads (86%) | hotspot (GDC flag); catalogued as CM021066, CM106373, COSV57326747, COSV57328428, COSV57342242, COSV57397137; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 59/169 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.5681C>T p.T1894M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs772701854, COSV58141531; called by muse, mutect2, varscan2
- ADCY8 | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV99654373; called by muse, mutect2, varscan2
- AMBN | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100534496; called by muse, mutect2, varscan2
- AMBRA1 | c.3620A>G p.Q1207R (on ENST00000458649 / NM_001367468.1; = p.Q1117R on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1271845591, COSV100095366; called by muse, mutect2, varscan2
- ANKRD17 | c.5842C>T p.R1948C | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100429997; called by muse, mutect2, varscan2
- BNC2 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.532); catalogued as rs767945913, COSV101034483, COSV66155172; called by muse, mutect2, varscan2
- CCDC178 | c.1400C>A p.T467N | Missense Mutation (SNP) | VAF 75/280 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs760077046, COSV55767541; called by muse, mutect2, varscan2
- CDK11A | c.1615_1628del p.K539Qfs*7 (on ENST00000378633 / NM_001313896.2; = p.K536Qfs*7 on NM_024011.4) | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as COSV52307932; called by mutect2, pindel, varscan2
- CFAP300 | c.393T>A p.D131E | Missense Mutation (SNP) | VAF 76/103 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as rs1223336318, COSV101462491; called by muse, mutect2, varscan2
- CHPF2 | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs146697508; called by muse, mutect2, varscan2
- CSMD1 | c.5503G>A p.V1835I (on ENST00000520002; = p.V1834I on NM_033225.6) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1419889005, COSV100153816; called by muse, mutect2, varscan2
- CTNNA2 | c.1342G>T p.V448F | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183190393, COSV100562058; called by muse, mutect2, varscan2
- CYP4A11 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100152640; called by muse, mutect2, varscan2
- DCDC1 | c.4843G>A p.E1615K (on ENST00000597505 / NM_001367979.1; = p.E722K on NM_020869.3) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs543178266, COSV58000674; called by muse, varscan2
- DENND3 | c.2615A>T p.E872V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs763068115, COSV99371696; called by muse, mutect2, varscan2
- FERMT1 | c.2012A>G p.K671R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752500262, COSV99452164; called by muse, mutect2, varscan2
- FNDC3B | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100394989; called by muse, varscan2
- IDH1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1229651962, COSV61620290; called by muse, mutect2, varscan2
- IGHV3-72 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.013); catalogued as rs765501202, COSV70409619; called by muse, mutect2, varscan2
- ITIH6 | c.3244G>A p.G1082R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141073311, COSV54492561, COSV99513400; called by muse, mutect2, varscan2
- KLK6 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs765571984, COSV59566303; called by muse, mutect2, varscan2
- KRTAP9-3 | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV101370189; called by muse, mutect2, varscan2
- LHX1 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs773502109; called by muse, mutect2, varscan2
- MROH2B | c.4284A>C p.E1428D | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV101270928; called by muse, mutect2, varscan2
- NDUFB10 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1567316047, COSV99238946; called by muse, mutect2, varscan2
- NPC1L1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs200072878, COSV99213515; called by muse, mutect2, varscan2
- OBSCN | c.9928G>A p.E3310K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.122); catalogued as rs1419348435, COSV52744426; called by muse, mutect2, varscan2
- PAPOLA | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.333); catalogued as rs755721143, COSV53479113, COSV99354693; called by muse, mutect2, varscan2
- PRAG1 | c.3850C>T p.Q1284* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100422845, COSV58157510; called by muse, mutect2, varscan2
- RBPJL | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV59213521; called by muse, mutect2, varscan2
- SLC12A7 | c.2607+1G>A p.X869_splice | Splice Site (SNP) | VAF 28/44 reads (64%) | catalogued as COSV99370581; called by muse, mutect2, varscan2
- SPANXN3 | c.426G>T p.*142Yext*14 | Nonstop Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV100980881, COSV65140913; called by muse, mutect2, varscan2
- STRIP2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs777011135, COSV50806981; called by muse, mutect2, varscan2
- STYXL2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs771502951; called by muse, mutect2
- TMEM184A | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52474930; called by muse, mutect2, varscan2
- TMPRSS15 | c.1588C>A p.L530M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519325; called by muse, mutect2, varscan2
- TSC2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs764529584, COSV54763779; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.70057C>A p.P23353T (on ENST00000591111; = p.P15929T on NM_003319.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | PolyPhen benign (0.013); catalogued as rs1416288780, COSV100630393; called by muse, mutect2, varscan2
- TTN | c.24660C>G p.D8220E (on ENST00000591111; = p.D7293E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/78 reads (54%) | PolyPhen benign (0.009); catalogued as COSV100630396; called by muse, mutect2, varscan2
- ATM | c.4923dup p.G1642Wfs*23 | Frame Shift Ins (INS) | VAF 15/25 reads (60%) | called by mutect2, pindel, varscan2
- KIAA1586 | c.1609del p.S537Qfs*20 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.589C>T p.R197* (on ENST00000621492; = p.R163* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- WASHC2C | c.3658A>C p.K1220Q (on ENST00000336378; = p.K1199Q on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ABCA4 | c.4194C>T p.G1398= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs763857670, COSV64679433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC136428.1 | c.162C>T p.S54= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV101434988; called by muse, mutect2, varscan2
- ADAMTS5 | c.468C>T p.F156= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs781071406, COSV53175455; called by muse, mutect2, varscan2
- AHSG | c.852C>T p.G284= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs762922913, COSV56608703; called by muse, mutect2, varscan2
- ATP8B2 | c.1863C>T p.Y621= (on ENST00000672630; = p.Y588= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs760108744, COSV59245042; called by muse, mutect2, varscan2
- BPIFB2 | c.801G>A p.A267= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs555124864, COSV50068326; called by muse, mutect2, varscan2
- C5 | c.3162G>A p.L1054= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV99798741; called by muse, mutect2, varscan2
- CACNG1 | c.60C>T p.I20= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs200565506, COSV99871784; called by muse, varscan2
- CDK17 | c.1420C>A p.R474= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as COSV54127319, COSV99703093; called by muse, mutect2, varscan2
- CSNK1A1L | c.15C>T p.S5= | Silent (SNP) | VAF 72/105 reads (69%) | catalogued as rs768049929, COSV65789336, COSV65789752; called by muse, mutect2, varscan2
- EPHA3 | c.1527C>A p.I509= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV60718006; called by muse, mutect2, varscan2
- FAT1 | c.7512C>T p.N2504= | Silent (SNP) | VAF 81/142 reads (57%) | catalogued as rs1002759839, COSV101499257; called by muse, mutect2, varscan2
- FTMT | c.183C>T p.P61= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1206980369, COSV58420621; called by muse, mutect2
- GNA12 | c.1056C>T p.T352= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs138692914, COSV99283042; called by muse, mutect2, varscan2
- KCNQ1 | c.1830C>T p.T610= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs774101297, COSV50130416, COSV99328499; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KLHL32 | c.552G>A p.T184= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs202093124, COSV65113937; called by muse, mutect2, varscan2
- MAP4K3 | c.132T>C p.I44= | Silent (SNP) | VAF 59/229 reads (26%) | catalogued as COSV99811140; called by muse, mutect2, varscan2
- MDN1 | c.8466C>A p.V2822= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV101021838; called by muse, mutect2, varscan2
- PNKP | c.990G>A p.K330= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs368069267; called by muse, mutect2, varscan2
- ROBO3 | c.4071C>T p.G1357= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV60626423; called by muse, mutect2, varscan2
- SPATA31A1 | c.1584G>A p.S528= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1184345832; called by muse, mutect2, varscan2
- TMPRSS9 | c.1803C>T p.G601= (on ENST00000648592; = p.G567= on NM_182973.2) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs766170841, COSV100211729; called by muse, mutect2, varscan2
- SSPOP | n.4346G>A | RNA (SNP) | VAF 8/34 reads (24%) | catalogued as rs377146636, COSV50487872; called by muse, mutect2, varscan2
